FM case AD6140 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/fbc43540-b9a4-4f93-bb18-c0ff5d6ed276

Female, 50.6 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
